Somatic mutation profile of tumor specimen ALCH-B1YA-TTP1-C (aliquot ALCH-B1YA-TTP1-C-2-0-D-A76N-36) from ALCHEMIST case ALCH-B1YA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 75.3 years (27,489 days).
Specimen ALCH-B1YA-TTP1-C: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47ca2749-c4d1-42a5-9d40-2876adf6c8ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1YA-NB1-A (Blood Derived Normal), aliquot ALCH-B1YA-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/210b371d-c4e3-4fa9-a3cd-c3bd5f9d00c2

The open-access MAF lists 57 somatic variants for this specimen: 40 protein-altering or splice-affecting, 9 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 9, Frame Shift Del 3, Intron 3, Nonsense Mutation 2, 3'UTR 2, 3'Flank 1, Splice Site 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL7A1 | c.5173G>A p.G1725R | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs772195825; ClinVar: pathogenic; called by muse, mutect2
- ACSL6 | c.139C>T p.R47W (on ENST00000379240; = p.R72W on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764258957, COSV57294780; called by muse, mutect2
- ADAMTS16 | c.401A>C p.K134T | Missense Mutation (SNP) | VAF 35/467 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as COSV57007529; called by muse, mutect2
- AHNAK | c.15517A>G p.I5173V | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as rs557788418; called by muse, mutect2, varscan2
- ALDOA | c.1196C>T p.P399L (on ENST00000642816 / NM_001243177.4; = p.P345L on NM_184041.5) | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.368); catalogued as rs1304593995; called by muse, mutect2
- BMP10 | c.948G>T p.R316S | Missense Mutation (SNP) | VAF 28/492 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54897810; called by muse, mutect2
- CTH | c.794G>T p.R265L | Missense Mutation (SNP) | VAF 22/388 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200263768; called by muse, mutect2
- HECW2 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 22/496 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1389991622, COSV53675157; called by muse, mutect2
- HOXB7 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 20/344 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763554332, COSV53311157; called by muse, mutect2
- LPA | c.209+1G>A p.X70_splice | Splice Site (SNP) | VAF 54/497 reads (11%) | catalogued as rs533200556, COSV60300564; called by muse, mutect2, varscan2
- METTL17 | c.1126C>T p.R376W | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1273908233; called by muse, mutect2
- OVOL3 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs746779875; called by muse, mutect2, varscan2
- SKOR2 | c.2864G>A p.R955Q | Missense Mutation (SNP) | VAF 15/175 reads (9%) | SIFT deleterious, low confidence (0); catalogued as rs1015535078; called by muse, mutect2
- TRMT6 | c.1018A>T p.K340* | Nonsense Mutation (SNP) | VAF 20/316 reads (6%) | catalogued as COSV99177522; called by muse, mutect2
- ZNF442 | c.488A>G p.N163S | Missense Mutation (SNP) | VAF 23/257 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1464797823; called by muse, mutect2
- ABI3BP | c.508A>T p.I170F | Missense Mutation (SNP) | VAF 25/258 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- AK7 | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 14/442 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.405); called by muse, mutect2
- AP4M1 | c.805A>C p.I269L | Missense Mutation (SNP) | VAF 14/462 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.092); called by muse, mutect2
- BRD2 | c.948G>T p.M316I | Missense Mutation (SNP) | VAF 11/242 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.01); called by muse, mutect2
- CDH13 | c.1136T>G p.V379G | Missense Mutation (SNP) | VAF 10/304 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CES1 | c.1182A>C p.E394D (on ENST00000361503 / NM_001025194.2; = p.E393D on NM_001266.5) | Missense Mutation (SNP) | VAF 22/673 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- DHCR24 | c.1526A>C p.K509T | Missense Mutation (SNP) | VAF 26/237 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAAF2 | c.1101del p.E368Sfs*73 | Frame Shift Del (DEL) | VAF 13/83 reads (16%) | called by mutect2, pindel, varscan2
- INTS1 | c.945G>T p.M315I | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- ISG20 | c.100C>G p.H34D | Missense Mutation (SNP) | VAF 16/233 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2
- KNTC1 | c.1384C>A p.L462I | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- LRRK2 | c.6969T>G p.I2323M | Missense Mutation (SNP) | VAF 16/273 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.203); called by muse, mutect2
- MPL | c.733G>T p.G245* | Nonsense Mutation (SNP) | VAF 34/336 reads (10%) | called by muse, mutect2, varscan2
- NMUR2 | c.329A>G p.Y110C | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- PROSER3 | c.1180del p.L394Cfs*29 | Frame Shift Del (DEL) | VAF 9/48 reads (19%) | called by mutect2, pindel, varscan2
- RYR3 | c.5014T>G p.F1672V | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.213); called by muse, mutect2
- SCARB1 | c.1175T>C p.L392P | Missense Mutation (SNP) | VAF 10/280 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); called by muse, mutect2
- SH3TC1 | c.460T>A p.F154I | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SRD5A1 | c.200C>G p.P67R | Missense Mutation (SNP) | VAF 25/435 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2
- SUMF2 | c.153del p.Q51Hfs*8 (on ENST00000652303; = p.Q32Hfs*8 on NM_015411.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/211 reads (9%) | called by mutect2, pindel, varscan2
- TRMT6 | c.1017A>T p.K339N | Missense Mutation (SNP) | VAF 20/320 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.145); called by muse, mutect2
- TSC2 | c.484G>T p.D162Y | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.866); called by muse, mutect2
- USP34 | c.10339T>A p.C3447S | Missense Mutation (SNP) | VAF 34/389 reads (9%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2
- VCAN | c.583C>A p.Q195K | Missense Mutation (SNP) | VAF 54/930 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- WDHD1 | c.2675A>T p.N892I | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- DERPC | c.144G>T p.S48= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as rs1413263592; called by muse, mutect2, varscan2
- ERBB4 | c.2544T>C p.N848= | Silent (SNP) | VAF 9/292 reads (3%) | catalogued as COSV100727013; called by muse, mutect2
- KCNN3 | c.621C>A p.P207= | Silent (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
- LENG8 | c.825G>T p.G275= | Silent (SNP) | VAF 18/108 reads (17%) | called by muse, mutect2
- NFE2L2 | c.24G>A p.P8= | Silent (SNP) | VAF 10/180 reads (6%) | catalogued as rs1485970982; called by muse, mutect2
- PURG | c.447G>A p.R149= | Silent (SNP) | VAF 16/286 reads (6%) | catalogued as COSV53306979; called by muse, mutect2
- SLAMF9 | c.618C>T p.I206= | Silent (SNP) | VAF 11/274 reads (4%) | called by muse, mutect2
- TMEM67 | c.243A>G p.L81= | Silent (SNP) | VAF 10/308 reads (3%) | called by muse, mutect2
- ZNF546 | c.1968C>T p.H656= | Silent (SNP) | VAF 23/308 reads (7%) | called by muse, mutect2
- ATL1 | c.283-20T>C | Intron (SNP) | VAF 20/206 reads (10%) | called by muse, mutect2
- ESRP1 | chr8:94639023 G>A | 5'Flank (SNP) | VAF 10/104 reads (10%) | catalogued as rs1163998410; called by muse, mutect2
- GALNT15 | chr3:16231809 A>G | 3'Flank (SNP) | VAF 26/426 reads (6%) | called by muse, mutect2
- HNRNPU | c.*83T>C | 3'UTR (SNP) | VAF 14/274 reads (5%) | called by muse, mutect2
- LINC01545 | n.260C>G | RNA (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- LRP8 | c.*22G>A | 3'UTR (SNP) | VAF 32/291 reads (11%) | called by muse, mutect2, varscan2
- RNASEH2C | c.468+10C>A | Intron (SNP) | VAF 18/177 reads (10%) | called by muse, mutect2, varscan2
- ZNF7 | c.3+30G>T | Intron (SNP) | VAF 6/151 reads (4%) | called by muse, mutect2
